CCDI case PBBTMS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a89939d5-18ca-465c-b3aa-715968d7e349

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.6 years (3,509 days).

Biospecimens (3 samples)
- Sample 0DGRG6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGRHK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGRHV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
